Somatic mutation profile of tumor specimen TCGA-77-6844-01A (aliquot TCGA-77-6844-01A-11D-1945-08) from TCGA case TCGA-77-6844, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.5 years (27,220 days).
Specimen TCGA-77-6844-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 124f8d04-4907-4f24-a28d-c29732e0abc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-6844-10A (Blood Derived Normal), aliquot TCGA-77-6844-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a13d9795-9352-4c6b-9b9f-6bdbef54b4b0

The open-access MAF lists 216 somatic variants for this specimen: 161 protein-altering or splice-affecting, 54 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 54, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 3, Splice Region 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.3889A>G p.K1297E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs571314877, COSV101201277; called by muse, mutect2, varscan2
- ABCA8 | c.4301C>A p.T1434N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752694814, COSV99067415; called by muse, mutect2, varscan2
- ACSL3 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100658057; called by muse, mutect2, varscan2
- ADAMTS12 | c.4063G>C p.D1355H | Missense Mutation (SNP) | VAF 114/190 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100711651, COSV61257949, COSV61268012; called by muse, mutect2, varscan2
- ADAMTS12 | c.3136C>A p.P1046T | Missense Mutation (SNP) | VAF 139/173 reads (80%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV100711654; called by muse, mutect2, varscan2
- ADGRG4 | c.6655A>C p.T2219P | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99796643; called by muse, mutect2, varscan2
- AP3B2 | c.2582C>T p.S861L (on ENST00000261722; = p.S855L on NM_004644.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.012); catalogued as rs753128051, COSV99916992; called by muse, mutect2, varscan2
- APOB | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99267888; called by muse, mutect2, varscan2
- APOBR | c.1169T>C p.L390P (on ENST00000431282; = p.L399P on NM_018690.4) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100112921; called by muse, mutect2, varscan2
- ATP11A | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119678, COSV99369864; called by muse, mutect2, varscan2
- BEND3 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100944678; called by muse, mutect2, varscan2
- BMI1 | c.678A>T p.R226S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100936496; called by muse, mutect2, varscan2
- BOC | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849333; called by muse, mutect2, varscan2
- BTBD11 | c.1661G>A p.C554Y (on ENST00000280758 / NM_001018072.2; = p.C91Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.543); catalogued as COSV99776933; called by muse, mutect2, varscan2
- C11orf16 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100393862; called by muse, mutect2, varscan2
- C12orf40 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV100210745; called by muse, mutect2, varscan2
- CACNA1E | c.216C>A p.F72L | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV100705145, COSV62392787; called by muse, mutect2, varscan2
- CARD6 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99621247, COSV99621277; called by muse, mutect2, varscan2
- CBR3 | c.628A>G p.R210G | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs758968014, COSV99289893; called by muse, mutect2, varscan2
- CGREF1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99565401; called by muse, varscan2
- CHPT1 | c.485dup p.C163Lfs*31 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | catalogued as rs755424899; called by mutect2, varscan2
- CHST6 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV100178323; called by muse, mutect2, varscan2
- CIC | c.3229A>C p.S1077R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV99360247; called by muse, mutect2, varscan2
- CLIP4 | c.793A>G p.M265V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs751811586, COSV100192380; called by muse, mutect2, varscan2
- CNOT4 | c.1443G>T p.Q481H (on ENST00000315544 / NM_001190848.1; = p.Q478H on NM_013316.4) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100212188; called by muse, mutect2, varscan2
- CNR1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.859); catalogued as COSV100759344; called by muse, mutect2, varscan2
- COL4A4 | c.4483T>A p.Y1495N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100307667; called by muse, mutect2, varscan2
- CRISPLD2 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99296017; called by muse, mutect2, varscan2
- CTNNA3 | c.1488del p.V497* | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as COSV65554396; called by mutect2, pindel, varscan2
- DNAH1 | c.1751A>T p.Y584F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs763341681, COSV101327002; called by muse, mutect2, varscan2
- DNAH5 | c.7859C>T p.S2620F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99453912; called by muse, mutect2, varscan2
- DNAH8 | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs112491228; called by muse, mutect2, varscan2
- DNER | c.983A>T p.K328M | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100519976; called by muse, mutect2, varscan2
- DOCK10 | c.4725G>T p.R1575S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99291511; called by muse, mutect2, varscan2
- DOCK10 | c.4724G>T p.R1575M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99291516; called by muse, mutect2, varscan2
- DOCK10 | c.930G>T p.L310= | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99290855; called by muse, mutect2, varscan2
- DPP10 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV59696274; called by muse, mutect2, varscan2
- DSCAM | c.2695C>A p.R899S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101261464, COSV68032377; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs370555773, COSV100668840; called by muse, mutect2, varscan2
- FAM91A1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV100593781; called by muse, mutect2
- FBLN7 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.395); catalogued as COSV99735000; called by muse, mutect2, varscan2
- FFAR1 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV50051598, COSV99323731; called by muse, mutect2, varscan2
- FLT4 | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99988872; called by muse, mutect2, varscan2
- GABPA | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100702520; called by muse, mutect2, varscan2
- GFRAL | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV100475871, COSV61232890; called by muse, mutect2, varscan2
- GOLM2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs771830526, CM143180, COSV100248062; called by muse, mutect2, varscan2
- GPR6 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV51571033; called by muse, mutect2
- GRM3 | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as rs1331153844, COSV100862870; called by muse, mutect2, varscan2
- H2AW | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100797319; called by muse, mutect2, varscan2
- HEATR6 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV99482601; called by muse, mutect2, varscan2
- HJURP | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100982632; called by muse, mutect2, varscan2
- HOXA5 | c.554T>G p.I185R | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99762484; called by muse, mutect2
- HOXD4 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100106521; called by muse, mutect2, varscan2
- HPX | c.213A>G p.K71= | Splice Region (SNP) | VAF 39/78 reads (50%) | catalogued as COSV99793548; called by muse, mutect2, varscan2
- HSPA4 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as COSV100507866; called by muse, mutect2, varscan2
- HTT | c.7387C>G p.Q2463E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100751223; called by muse, mutect2, varscan2
- INPP5D | c.3277G>A p.E1093K (on ENST00000445964 / NM_001017915.3; = p.E1092K on NM_005541.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.137); catalogued as rs1291861636, COSV64036226; called by muse, mutect2
- IQGAP2 | c.2704C>A p.L902M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167988; called by muse, mutect2, varscan2
- JAKMIP1 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV51530671, COSV99290708; called by muse, mutect2, varscan2
- KCNA5 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52904329; called by muse, mutect2, varscan2
- KCNC2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54364357, COSV54375730; called by muse, mutect2, varscan2
- KCNQ5 | c.1438A>G p.K480E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100573615, COSV59655979; called by muse, mutect2, varscan2
- KIAA0232 | c.1555T>G p.L519V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1227375896, COSV100301092; called by muse, mutect2, varscan2
- KIT | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV55391366; called by muse, mutect2, varscan2
- KYNU | c.815G>C p.W272S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933982; called by muse, mutect2, varscan2
- LDLRAD4 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.999); catalogued as rs767854509, COSV63334778; called by muse, mutect2, varscan2
- LIFR | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99665431; called by muse, mutect2
- LRFN5 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99985363; called by muse, mutect2, varscan2
- LRP5 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99592598; called by muse, mutect2, varscan2
- LY75 | c.4463G>C p.C1488S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99716991; called by muse, mutect2, varscan2
- MAGEE1 | c.2857G>C p.V953L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100819517; called by muse, mutect2, varscan2
- MAST2 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as rs1455204541, COSV63617456; called by muse, mutect2, varscan2
- MAZ | c.841T>A p.C281S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99361477; called by muse, mutect2, varscan2
- MGA | c.2810del p.K937Rfs*57 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as COSV54948971; called by mutect2, pindel, varscan2
- MLH3 | c.3941A>G p.N1314S (on ENST00000355774 / NM_001040108.2; = p.N1290S on NM_014381.3) | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs200444835, COSV99470676; called by muse, mutect2, varscan2
- MORC3 | c.1209-2A>G p.X403_splice | Splice Site (SNP) | VAF 23/86 reads (27%) | catalogued as COSV101247763; called by muse, mutect2, varscan2
- MS4A6A | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); catalogued as rs763824515, COSV60616937, COSV60620281; called by muse, mutect2
- MSC | c.133T>A p.S45T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.206); catalogued as COSV100335892; called by muse, mutect2, varscan2
- MTMR4 | c.1969A>G p.S657G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100051425; called by muse, mutect2, varscan2
- MUC5AC | c.15102G>C p.E5034D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.649); catalogued as rs1374888122, COSV100611587; called by muse, mutect2, varscan2
- MYH15 | c.4678G>C p.E1560Q | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV99844248; called by muse, mutect2, varscan2
- NCKAP1L | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53203606, COSV99515275; called by muse, mutect2, varscan2
- NCOR1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51963688, COSV99251936; called by muse, mutect2, varscan2
- NCOR2 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100657856; called by muse, mutect2, varscan2
- NID2 | c.1157G>T p.W386L | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99357210; called by muse, mutect2, varscan2
- NKAIN3 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136466; called by muse, mutect2, varscan2
- NUP155 | c.448G>A p.V150M (on ENST00000231498 / NM_153485.3; = p.V91M on NM_004298.4) | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194735; called by muse, mutect2, varscan2
- NUP155 | c.296-2A>T p.X99_splice (on ENST00000231498 / NM_153485.3; = p.X40_splice on NM_004298.4) | Splice Site (SNP) | VAF 90/114 reads (79%) | catalogued as COSV99194737; called by muse, mutect2, varscan2
- OR4C46 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100060981; called by muse, mutect2, varscan2
- OR5T3 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs780288281, COSV100282917, COSV57380033; called by muse, mutect2, varscan2
- OR8B8 | c.191A>T p.Y64F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100045241; called by muse, mutect2, varscan2
- P2RY10 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99409024, COSV99409383; called by muse, mutect2, varscan2
- PCDHA11 | c.213T>A p.H71Q | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV100252498; called by muse, mutect2, varscan2
- PCDHA11 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV100254208, COSV56485489; called by muse, varscan2
- PCDHA6 | c.972C>A p.D324E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100972518; called by muse, mutect2, varscan2
- PCOLCE2 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV99930928; called by muse, mutect2
- PDILT | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs764322281, COSV100199827; called by muse, mutect2, varscan2
- PIK3CG | c.1285C>A p.L429M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100783160; called by muse, mutect2, varscan2
- PLAAT1 | c.389G>A p.R130H (on ENST00000650797; = p.R25H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs150318874; called by muse, mutect2, varscan2
- PLCB4 | c.3138G>T p.Q1046H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99596877; called by muse, mutect2, varscan2
- PLEK | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV99311226; called by muse, mutect2, varscan2
- PNP | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100829013; called by muse, mutect2, varscan2
- PREX1 | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.079); catalogued as rs376311381, COSV100906795; called by muse, mutect2, varscan2
- RAB29 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 99/227 reads (44%) | catalogued as COSV52520697, COSV99353133; called by muse, mutect2, varscan2
- RARS2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV101057011; called by muse, mutect2, varscan2
- RBM46 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55978137; called by muse, mutect2, varscan2
- RD3 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV100879232, COSV65362768; called by muse, mutect2, varscan2
- RIMS1 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.047); catalogued as COSV99330272; called by muse, mutect2
- RNFT1 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99994556; called by muse, mutect2, varscan2
- RORC | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs267598019, COSV100561905, COSV100562096; called by muse, mutect2, varscan2
- RPP40 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100124142; called by muse, mutect2, varscan2
- RPS6KA1 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100943305; called by muse, mutect2, varscan2
- RUFY3 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV99887877; called by muse, mutect2, varscan2
- RYR2 | c.3595G>C p.D1199H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100772734, COSV63690527; called by muse, mutect2, varscan2
- S100A3 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100573152, COSV62876500; called by muse, mutect2, varscan2
- SCN5A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs199473047, CM087452, COSV100028520; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SDK2 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV101168526; called by muse, mutect2, varscan2
- SEMA4D | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs775445061, COSV100358780; called by muse, mutect2, varscan2
- SH2D3C | c.1670C>A p.T557N (on ENST00000314830 / NM_170600.3; = p.T400N on NM_005489.4) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100137509; called by muse, mutect2, varscan2
- SIM2 | c.916T>C p.W306R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750059338, COSV99293592; called by muse, mutect2, varscan2
- SLC17A2 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV55355245, COSV99614944; called by muse, mutect2
- SLC18B1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV99259331; called by muse, mutect2, varscan2
- SLC26A7 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99404294; called by muse, mutect2, varscan2
- SLCO5A1 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); catalogued as COSV99480988; called by muse, mutect2, varscan2
- SLFN11 | c.1910G>T p.R637M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV100391004; called by muse, mutect2, varscan2
- SOS2 | c.3544C>A p.P1182T | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.601); catalogued as COSV53572369, COSV99366757; called by muse, mutect2, varscan2
- SOX8 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.719); catalogued as COSV99559377; called by muse, mutect2, varscan2
- SPAG1 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs1339546837, COSV99309456; called by muse, mutect2, varscan2
- SPDYC | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV101017304; called by muse, mutect2, varscan2
- STAB1 | c.7283C>A p.A2428D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.123); catalogued as COSV100195437; called by muse, mutect2, varscan2
- STX4 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100572985, COSV58269020; called by muse, mutect2, varscan2
- SV2A | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100975225, COSV100975265; called by muse, mutect2, varscan2
- TAS2R8 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV53689258; called by muse, mutect2, varscan2
- TECRL | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1409531996, COSV101169360; called by muse, mutect2, varscan2
- TECRL | c.591C>A p.Y197* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV101169362; called by muse, mutect2, varscan2
- TLN1 | c.4904G>C p.G1635A | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as COSV100148217; called by muse, mutect2, varscan2
- TMEM192 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV100122206; called by muse, mutect2, varscan2
- TMTC2 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100338820; called by muse, mutect2, varscan2
- TPR | c.3970G>C p.E1324Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100824242; called by muse, mutect2, varscan2
- TRIM48 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV101338352; called by muse, mutect2, varscan2
- TRPC1 | c.1031G>A p.R344H (on ENST00000476941 / NM_001251845.2; = p.R310H on NM_003304.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1172161848, COSV56425438, COSV56431359; called by muse, mutect2, varscan2
- TTLL7 | c.1670G>T p.S557I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV53088956, COSV99553190; called by muse, mutect2, varscan2
- TTN | c.13238G>A p.R4413Q (on ENST00000591111; = p.R4367Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | PolyPhen benign (0.182); catalogued as rs202017278, COSV60380608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USF3 | c.3429G>T p.Q1143H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100325774; called by muse, mutect2, varscan2
- USHBP1 | c.1571A>T p.H524L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99394526; called by muse, mutect2, varscan2
- USP28 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50158458, COSV99136624; called by muse, mutect2, varscan2
- WDR26 | c.1725A>T p.L575F (on ENST00000414423 / NM_001379403.1; = p.L475F on NM_025160.7) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99691532; called by muse, mutect2, varscan2
- XPO6 | c.2805G>C p.K935N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100485350; called by muse, mutect2, varscan2
- ZMYM1 | c.1527A>T p.K509N | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV100721064; called by muse, mutect2
- ZMYM1 | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1201093254, COSV100721065; called by muse, mutect2, varscan2
- ZNF479 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58638045; called by muse, mutect2, varscan2
- ZNF567 | c.1800G>T p.Q600H (on ENST00000536254 / NM_001322913.1; = p.Q569H on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV100658979; called by muse, mutect2, varscan2
- AMPH | c.1724del p.P575Rfs*35 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- CTNND2 | c.2457del p.D820Ifs*6 | Frame Shift Del (DEL) | VAF 88/840 reads (10%) | called by pindel, varscan2
- GTF2IRD2B | c.1982G>T p.C661F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NCAN | c.3233del p.G1078Afs*46 | Frame Shift Del (DEL) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- NFX1 | c.725_726insT p.Q243Tfs*43 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by pindel, varscan2
- PTEN | c.421_440del p.H141Gfs*32 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- TPTE | c.452A>T p.Q151L (on ENST00000618007 / NM_199261.4; = p.Q133L on NM_199259.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by mutect2, varscan2
- ABCG8 | c.471G>C p.L157= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99700243; called by muse, mutect2, varscan2
- ACKR1 | c.186G>T p.L62= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100929654; called by muse, mutect2, varscan2
- ADAMTSL2 | c.756C>T p.D252= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs373333467; called by muse, mutect2, varscan2
- ADGRA2 | c.1047T>C p.S349= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100178401; called by muse, mutect2, varscan2
- AGXT | c.633G>T p.L211= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100280358; called by muse, mutect2, varscan2
- AHDC1 | c.3267C>T p.S1089= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1224763779, COSV99899731; called by muse, mutect2, varscan2
- ALPI | c.426G>T p.T142= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99786150; called by muse, mutect2, varscan2
- ANG | c.441G>A p.P147= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs759928848, COSV100390988; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP10A | c.1551G>A p.L517= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV63515409; called by muse, mutect2, varscan2
- BCLAF1 | c.1722A>C p.T574= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1428038860, COSV100786982; called by muse, mutect2, varscan2
- CENPQ | c.270A>T p.S90= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100225859; called by muse, mutect2, varscan2
- CROCC | c.2763C>T p.A921= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100978395; called by muse, mutect2, varscan2
- CTNNA3 | c.2595G>A p.E865= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV101041609; called by muse, mutect2, varscan2
- DNAH7 | c.8775T>C p.Y2925= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100417443; called by muse, mutect2, varscan2
- FAT4 | c.918G>T p.T306= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV101272739, COSV67889922; called by muse, mutect2, varscan2
- FSIP2 | c.20118G>C p.T6706= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs779866454, COSV58090474, COSV58100545; called by muse, mutect2, varscan2
- HTR3C | c.1125C>T p.T375= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100570754; called by muse, mutect2, varscan2
- KATNIP | c.1539C>T p.H513= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs761446546, COSV99851952; called by muse, mutect2, varscan2
- KIR2DL4 | c.1221C>A p.A407= (on ENST00000396284; = p.A333= on NM_001080770.2) | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- MAP3K5 | c.1641C>T p.V547= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs761807279, COSV62890502; called by muse, mutect2, varscan2
- MDGA2 | c.1296T>C p.A432= (on ENST00000399232 / NM_001113498.2; = p.A134= on NM_182830.4) | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as COSV62096011; called by muse, mutect2, varscan2
- MMS22L | c.1359G>A p.K453= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99247680; called by muse, mutect2, varscan2
- MYH4 | c.1437G>T p.L479= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV55111708, COSV55125660; called by muse, mutect2, varscan2
- NACA | c.171T>A p.A57= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100771616; called by muse, mutect2, varscan2
- NLRC5 | c.4779C>A p.V1593= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99348184; called by muse, mutect2, varscan2
- NLRP3 | c.3078G>T p.L1026= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100275047, COSV100276616; called by muse, mutect2, varscan2
- NUP98 | c.4053G>A p.Q1351= (on ENST00000359171 / NM_001365126.1; = p.Q1334= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV100263408; called by muse, mutect2, varscan2
- OR10G3 | c.213T>C p.D71= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100336145; called by muse, mutect2, varscan2
- OR13G1 | c.541T>C p.L181= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100687544; called by muse, mutect2, varscan2
- OR1A1 | c.894C>T p.A298= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1567526311, COSV100410831; called by muse, mutect2, varscan2
- OR2T6 | c.564C>A p.A188= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100861634; called by muse, mutect2, varscan2
- OR8D2 | c.399T>C p.N133= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs781405818, COSV100659100; called by muse, mutect2, varscan2
- OR8G5 | c.738G>T p.S246= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs749385742, COSV100422653; called by muse, varscan2
- PRAME | c.1311C>A p.T437= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV101287238; called by muse, mutect2, varscan2
- PRMT7 | c.522G>T p.V174= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100267250; called by muse, mutect2, varscan2
- PROM2 | c.2160C>T p.A720= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100469371; called by muse, mutect2, varscan2
- PYGL | c.1350C>G p.S450= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV99369066; called by muse, mutect2, varscan2
- RAB29 | c.366C>G p.L122= | Silent (SNP) | VAF 126/293 reads (43%) | catalogued as COSV99353132; called by muse, mutect2, varscan2
- RALGAPA2 | c.4005A>T p.P1335= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs553430727, COSV99174951; called by muse, mutect2, varscan2
- RGS6 | c.723G>A p.Q241= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV100666964; called by muse, mutect2, varscan2
- RIMS1 | c.762T>G p.P254= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99330273; called by muse, mutect2
- SASH1 | c.1854G>A p.E618= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100821432, COSV66560735; called by muse, mutect2
- SGMS1 | c.738G>A p.P246= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs759281143, COSV62370996; called by muse, mutect2, varscan2
- SNX29 | c.1836C>T p.A612= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1369901247, COSV100030078; called by muse, mutect2, varscan2
- TAP1 | c.657C>T p.S219= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100841311; called by muse, mutect2, varscan2
- TOP1MT | c.345C>T p.F115= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as COSV100239750; called by muse, mutect2, varscan2
- TSC2 | c.1152C>T p.V384= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99555243; called by muse, mutect2, varscan2
- TTN | c.101244A>T p.I33748= (on ENST00000591111; = p.I26324= on NM_003319.4) | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100628914; called by muse, mutect2, varscan2
- UGT1A6 | c.1308G>A p.K436= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100530981; called by muse, mutect2, varscan2
- VCPIP1 | c.2847C>G p.T949= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100125777; called by muse, mutect2, varscan2
- VWA5A | c.2142A>G p.A714= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100827960; called by muse, mutect2, varscan2
- WWC1 | c.3318A>C p.P1106= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99515846; called by muse, mutect2, varscan2
- ZFHX3 | c.6423C>G p.L2141= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99214559; called by muse, mutect2, varscan2
- ZNF154 | c.148T>C p.L50= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV101377546; called by muse, mutect2, varscan2
- NTRK3 | c.1586-38603C>A | Intron (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100448017; called by muse, mutect2, varscan2
